Somatic mutation profile of tumor specimen TCGA-PJ-A5Z8-01A (aliquot TCGA-PJ-A5Z8-01A-11D-A28G-10) from TCGA case TCGA-PJ-A5Z8, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 60.1 years (21,968 days).
Specimen TCGA-PJ-A5Z8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86e86a38-831b-4925-8e9a-98472b112352.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PJ-A5Z8-10A (Blood Derived Normal), aliquot TCGA-PJ-A5Z8-10A-01D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f11e4baf-4ab2-4542-8ac2-24a2914b2fdc

The open-access MAF lists 75 somatic variants for this specimen: 60 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 13, Frame Shift Del 8, Frame Shift Ins 6, Splice Site 3, In Frame Del 1, 3'UTR 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.14164A>C p.N4722H | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.204); catalogued as COSV68946168; called by muse, mutect2, varscan2
- AC100868.1 | c.1669T>A p.C557S | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51841819; called by muse, mutect2, varscan2
- AC100868.1 | c.1668G>A p.R556= | Splice Region (SNP) | VAF 13/90 reads (14%) | catalogued as COSV51841843, COSV99226478; called by muse, mutect2, varscan2
- ACSF2 | c.641C>G p.T214S | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.101); catalogued as COSV51972235; called by muse, mutect2, varscan2
- ADH6 | c.741A>T p.L247F | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52956002; called by muse, mutect2, varscan2
- ANK3 | c.7297G>T p.D2433Y | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV55055703; called by muse, mutect2, varscan2
- ANKRD35 | c.2923C>T p.H975Y | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs782708746, COSV62910169; called by muse, mutect2, varscan2
- ARID1A | c.4523A>G p.Y1508C | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61376579; called by muse, mutect2, varscan2
- CHD3 | c.469C>G p.H157D | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.396); catalogued as COSV57874624; called by muse, mutect2, varscan2
- CLEC18B | c.472T>A p.S158T | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.928); catalogued as COSV60577342; called by muse, mutect2
- COPG1 | c.2320G>T p.A774S | Missense Mutation (SNP) | VAF 56/284 reads (20%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.958); catalogued as COSV59113820; called by muse, mutect2, varscan2
- COPG1 | c.2321C>A p.A774E | Missense Mutation (SNP) | VAF 56/284 reads (20%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.987); catalogued as COSV59113834; called by muse, mutect2, varscan2
- CYP17A1 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777638364, CM940326, COSV64004889; called by muse, mutect2, varscan2
- CYP17A1 | c.943C>A p.L315M | Missense Mutation (SNP) | VAF 54/243 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV100882092, COSV64004891; called by muse, mutect2, varscan2
- DNAJC14 | c.1506G>C p.E502D | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.635); catalogued as COSV54478303; called by muse, mutect2, varscan2
- DNMBP | c.1728C>A p.H576Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.299); catalogued as COSV60624453; called by muse, mutect2, varscan2
- EFR3A | c.1692T>G p.N564K | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as COSV54456326; called by muse, mutect2, varscan2
- ENTPD7 | c.20C>A p.S7Y | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.542); catalogued as COSV65112230; called by muse, mutect2, varscan2
- GLS | c.1547A>G p.H516R | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV57841350; called by muse, mutect2, varscan2
- GRID2 | c.2011C>T p.L671F | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56199386, COSV56207230; called by muse, mutect2
- GRK5 | c.1674+1G>A p.X558_splice | Splice Site (SNP) | VAF 8/46 reads (17%) | catalogued as COSV64866291; called by mutect2, varscan2
- HECW1 | c.1304C>A p.P435H | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.293); catalogued as COSV67828157; called by muse, mutect2, varscan2
- HPSE | c.417G>C p.K139N | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.146); catalogued as COSV60986631; called by muse, mutect2, varscan2
- IMMT | c.1740G>T p.M580I | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.046); catalogued as COSV54479849; called by muse, mutect2, varscan2
- IQGAP2 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV57172526; called by muse, mutect2, varscan2
- LARP7 | c.811C>A p.Q271K | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV60520772; called by muse, mutect2, varscan2
- LEFTY1 | c.530C>A p.A177D | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV55282802; called by muse, mutect2, varscan2
- LGALS12 | c.784C>A p.Q262K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV55370057; called by muse, mutect2, varscan2
- LMAN1L | c.499G>T p.D167Y | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.095); catalogued as COSV59001729; called by muse, mutect2, varscan2
- LRP5 | c.2665G>T p.V889L | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as COSV53711525, COSV53714907; called by muse, mutect2, varscan2
- MIS18BP1 | c.2609G>A p.C870Y | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.321); catalogued as COSV60370588; called by muse, mutect2, varscan2
- MMP15 | c.1683G>C p.E561D | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.474); catalogued as COSV54679515; called by muse, mutect2, varscan2
- MSS51 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.36); catalogued as COSV55019104; called by muse, mutect2, varscan2
- MTA1 | c.1913dup p.S639Lfs*18 | Frame Shift Ins (INS) | VAF 22/114 reads (19%) | catalogued as rs1555433939; called by mutect2, varscan2
- NKD1 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV51690916; called by muse, mutect2, varscan2
- NLRP6 | c.2225A>G p.D742G | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.977); catalogued as rs150530901; called by muse, mutect2
- PGAP1 | c.146A>T p.Q49L | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.608); catalogued as COSV61325768; called by muse, mutect2, varscan2
- PKP1 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 49/190 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.33); catalogued as COSV55820973, COSV55822250; called by muse, mutect2, varscan2
- PLXNB2 | c.4888-2A>G p.X1630_splice | Splice Site (SNP) | VAF 15/114 reads (13%) | catalogued as COSV63781322; called by muse, mutect2, varscan2
- SLC40A1 | c.382G>T p.V128F | Missense Mutation (SNP) | VAF 41/202 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV53722773; called by muse, mutect2, varscan2
- SLC47A1 | c.277T>C p.S93P | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs756312668, COSV54500803; called by muse, mutect2, varscan2
- SMYD5 | c.245A>G p.E82G | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV50264711; called by muse, mutect2, varscan2
- ST8SIA2 | c.929T>A p.I310N | Missense Mutation (SNP) | VAF 16/68 reads (24%) | PolyPhen probably damaging (0.999); catalogued as COSV51569002; called by muse, mutect2, varscan2
- TAF5L | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51079502; called by muse, mutect2
- ACACA | c.2579C>A p.P860H | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- CDH12 | c.2355del p.E786Rfs*59 | Frame Shift Del (DEL) | VAF 28/121 reads (23%) | called by mutect2, pindel, varscan2
- FHL5 | c.461_462del p.C154Ffs*2 | Frame Shift Del (DEL) | VAF 30/137 reads (22%) | called by mutect2, pindel, varscan2
- HEATR5B | c.1873dup p.C625Lfs*3 | Frame Shift Ins (INS) | VAF 47/255 reads (18%) | called by mutect2, pindel, varscan2
- KDM1B | c.2373del p.F793Sfs*19 (on ENST00000449850; = p.F560Sfs*19 on NM_153042.4) | Frame Shift Del (DEL) | VAF 18/93 reads (19%) | called by mutect2, pindel, varscan2
- LAMA3 | c.8248_8251del p.L2750Mfs*6 (on ENST00000313654 / NM_198129.4; = p.L1141Mfs*6 on NM_000227.6) | Frame Shift Del (DEL) | VAF 39/190 reads (21%) | called by mutect2, pindel, varscan2
- LAMB1 | c.3186_3197delinsC p.Q1063Pfs*16 | Frame Shift Del (DEL) | VAF 27/206 reads (13%) | called by pindel, varscan2*
- MON2 | c.3488dup p.A1164Gfs*21 | Frame Shift Ins (INS) | VAF 9/44 reads (20%) | called by mutect2, pindel, varscan2
- MYH3 | c.101_102del p.A34Efs*31 | Frame Shift Del (DEL) | VAF 32/157 reads (20%) | called by mutect2, pindel, varscan2
- NUP98 | c.803del p.T268Kfs*41 | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- OSGIN2 | c.494dup p.G167Rfs*14 | Frame Shift Ins (INS) | VAF 13/80 reads (16%) | called by mutect2, pindel, varscan2
- POLR1B | c.2219_2224del p.N740_A741del | In Frame Del (DEL) | VAF 21/125 reads (17%) | called by mutect2, pindel
- RDH16 | c.626del p.F209Sfs*5 | Frame Shift Del (DEL) | VAF 27/88 reads (31%) | called by mutect2, pindel, varscan2
- TRPC4AP | c.1317_1318insTT p.H440Ffs*16 | Frame Shift Ins (INS) | VAF 30/139 reads (22%) | called by mutect2, pindel, varscan2
- VPS8 | c.1782_1796del p.X594_splice (on ENST00000625842 / NM_001349294.1; = p.X592_splice on NM_015303.3 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 12/44 reads (27%) | called by mutect2, pindel, varscan2
- ZBTB1 | c.1035dup p.K346* | Frame Shift Ins (INS) | VAF 31/144 reads (22%) | called by mutect2, pindel, varscan2
- COX10 | c.447A>G p.Q149= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as COSV55404741; called by muse, mutect2, varscan2
- CTDNEP1 | c.642T>C p.L214= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV56641871; called by muse, mutect2, varscan2
- DCAF17 | c.1143T>A p.S381= | Silent (SNP) | VAF 27/135 reads (20%) | catalogued as COSV59830198; called by muse, mutect2, varscan2
- DDX54 | c.1242C>T p.S414= | Silent (SNP) | VAF 67/194 reads (35%) | catalogued as rs1413676452, COSV58373221; called by muse, mutect2, varscan2
- GKN1 | c.441A>G p.T147= | Silent (SNP) | VAF 38/194 reads (20%) | catalogued as COSV65006466; called by muse, mutect2, varscan2
- LRRC37A3 | c.4482T>A p.I1494= | Silent (SNP) | VAF 85/398 reads (21%) | catalogued as COSV58535149; called by muse, mutect2, varscan2
- MC5R | c.684G>A p.A228= | Silent (SNP) | VAF 28/119 reads (24%) | catalogued as COSV61253842; called by muse, mutect2, varscan2
- MRC2 | c.1716C>A p.I572= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV57639319; called by muse, mutect2, varscan2
- MRGPRX4 | c.294C>T p.L98= | Silent (SNP) | VAF 31/175 reads (18%) | catalogued as rs267602809, COSV58590244; called by muse, mutect2, varscan2
- PRDM15 | c.2124G>A p.L708= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as COSV54151997; called by muse, mutect2, varscan2
- SGO2 | c.3420T>G p.S1140= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV63415087; called by muse, mutect2, varscan2
- ST8SIA2 | c.930C>T p.I310= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV51569027; called by muse, mutect2, varscan2
- STOML1 | c.441T>C p.F147= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV57551532; called by muse, mutect2, varscan2
- DDX41 | c.*334G>C | 3'UTR (SNP) | VAF 26/124 reads (21%) | catalogued as COSV57252016; called by muse, mutect2, varscan2
- EPS8L1 | c.429+232C>G | Intron (SNP) | VAF 26/144 reads (18%) | catalogued as COSV99135947; called by muse, mutect2, varscan2
